Somatic mutation profile of tumor specimen MP2PRT-PAPMWX-TMP1-A (aliquot MP2PRT-PAPMWX-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPMWX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,100 days).
Specimen MP2PRT-PAPMWX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1e23283-ce29-4b83-ab94-c0e64b5cc490.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPMWX-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPMWX-NM1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ab8e1ff-b825-4b7e-b6b1-3d8eb4f404f2

The open-access MAF lists 14 somatic variants for this specimen: 14 protein-altering or splice-affecting.
By variant classification: Missense Mutation 13, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 116/280 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BAZ1A | c.749A>G p.K250R | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV62408942; called by muse, mutect2, varscan2
- CLEC2L | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 121/262 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as COSV70691624; called by muse, mutect2, varscan2
- CREBBP | c.4420T>G p.C1474G | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52128214; called by muse, mutect2, varscan2
- DNAH5 | c.7502G>A p.R2501Q | Missense Mutation (SNP) | VAF 50/679 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs78853309, CM065122, COSV54218323; called by muse, mutect2
- FIZ1 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 75/520 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.172); catalogued as rs1468224901; called by muse, mutect2, varscan2
- PCDHA2 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 31/512 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.902); catalogued as rs145951382, COSV65370805; called by muse, mutect2
- ZNF219 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 57/746 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as COSV53882099; called by muse, mutect2
- ACSL3 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MFSD10 | c.896delinsTAGCGG p.Q299Lfs*43 | Frame Shift Ins (INS) | VAF 95/346 reads (27%) | called by pindel, varscan2*
- NMRK2 | c.116A>T p.K39M | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RBMXL3 | c.1415A>T p.E472V | Missense Mutation (SNP) | VAF 54/491 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SWT1 | c.2279A>G p.E760G | Missense Mutation (SNP) | VAF 101/245 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF318 | c.5346A>T p.K1782N | Missense Mutation (SNP) | VAF 116/425 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
